Somatic mutation profile of tumor specimen MMRF_1501_1_BM_CD138pos (aliquot MMRF_1501_1_BM_CD138pos_T2_KAS5U_L02372) from MMRF case MMRF_1501, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,856 days).
Specimen MMRF_1501_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b12655b7-2b90-4377-af7f-800d9c9e2d02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1501_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1501_1_PB_Whole_C3_KAS5U_L02380; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e0e0dc2-7439-4a78-92f0-08b0a9a33341

The open-access MAF lists 170 somatic variants for this specimen: 62 protein-altering or splice-affecting, 29 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 46, Silent 29, Intron 23, 5'UTR 5, 3'Flank 3, Splice Region 3, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP7 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs769238453, COSV58698523; called by muse, mutect2, varscan2
- ADCY2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs143227108; called by muse, mutect2, varscan2
- ALG9 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101211859; called by muse, mutect2
- CEP120 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV60265960; called by muse, mutect2
- CFAP61 | c.2261T>C p.V754A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs535287440; called by muse, mutect2, varscan2
- CHERP | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV52225554; called by muse, mutect2
- COL6A3 | c.5183T>C p.V1728A | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55086722; called by muse, mutect2, varscan2
- FRMD4B | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1248893016; called by muse, mutect2, varscan2
- GLI3 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM107018, COSV67885094; called by muse, mutect2, varscan2
- KLKB1 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV52996919; called by muse, mutect2
- MCF2L | c.2752G>A p.A918T (on ENST00000375608; = p.A886T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs201538160, COSV56176175; called by muse, mutect2, varscan2
- MYO1E | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 25/42 reads (60%) | catalogued as rs543195936; called by muse, mutect2, varscan2
- NIN | c.1773C>T p.H591= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as rs750117145; called by muse, mutect2, varscan2
- OR5J2 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.811); catalogued as COSV56621068; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- SLC25A40 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1385819913; called by muse, mutect2
- SLC37A4 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs374848317, COSV100421593; called by muse, mutect2
- SMIM8 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs755461432, COSV57640328, COSV57640417; called by muse, mutect2
- TBC1D10B | c.2299C>T p.R767W | Missense Mutation (SNP) | VAF 93/164 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs150663146; called by muse, mutect2, varscan2
- TUBD1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 60/482 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs146943916; called by muse, mutect2, varscan2
- WWC1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1384688280; called by muse, mutect2, varscan2
- APOA2 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ARHGAP33 | c.2528G>A p.R843K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BRWD3 | c.1193G>T p.W398L | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf158 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CA8 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- CACNA1A | c.1403T>G p.F468C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CBX2 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 19/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CCDC14 | c.775G>T p.V259F (on ENST00000488653; = p.V211F on NM_022757.5) | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- CLUH | c.180C>A p.F60L (on ENST00000435359; = p.F98L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, varscan2
- DCHS1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2
- DDX25 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX33 | c.412A>G p.R138G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDNRB | c.664A>G p.M222V (on ENST00000377211 / NM_001201397.1; = p.M132V on NM_000115.5) | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ERG | c.1429C>T p.H477Y (on ENST00000398919 / NM_001243428.1; = p.H453Y on NM_004449.4) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GFRAL | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GNAS | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 142/278 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- IGHV2-70D | c.342T>A p.Y114* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | called by muse, varscan2
- IGHV2-70D | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, varscan2
- IGHV2-70D | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, varscan2
- ITGA6 | c.1796A>T p.K599I (on ENST00000442250; = p.K560I on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- MCM3AP | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2
- MED12 | c.1133T>G p.V378G | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MORC1 | c.760A>C p.I254L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2
- MYH8 | c.5290G>A p.D1764N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR6M1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PLCD3 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PRB4 | c.202T>A p.S68T | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PREX2 | c.4707G>A p.Q1569= | Splice Region (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- PSD | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- RAI14 | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SLTM | c.1898+2T>C p.X633_splice | Splice Site (SNP) | VAF 154/319 reads (48%) | called by muse, mutect2, varscan2
- SOD3 | c.394_408del p.Y132_A136del | In Frame Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2*
- TLK2 | c.718A>C p.R240= | Splice Region (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- TMEM181 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSGA10 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- UBE2E3 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2
- WNT3A | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YTHDF2 | c.1691A>G p.Q564R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- ZBBX | c.2284G>T p.G762* | Nonsense Mutation (SNP) | VAF 38/454 reads (8%) | called by muse, mutect2
- ZIC1 | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF496 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ACTR3 | c.75A>G p.T25= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- ADD3 | c.999C>T p.L333= | Silent (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- B4GALT2 | c.561C>T p.D187= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, varscan2
- BCL11B | c.2280G>T p.L760= (on ENST00000357195 / NM_001282237.2; = p.L689= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- CCDC185 | c.1128G>T p.V376= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- CFAP47 | c.4797C>G p.L1599= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV57977373; called by muse, mutect2, varscan2
- CLUH | c.120C>T p.V40= (on ENST00000435359; = p.V78= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- CNOT2 | c.1092C>T p.I364= | Silent (SNP) | VAF 26/287 reads (9%) | catalogued as COSV57501041; called by muse, mutect2
- COMMD4 | c.222C>T p.F74= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV51190183; called by muse, mutect2
- CSNK1D | c.1131C>T p.A377= | Silent (SNP) | VAF 65/147 reads (44%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3528C>A p.R1176= (on ENST00000321322; = p.R1116= on NM_020693.4) | Silent (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- ENTPD4 | c.471G>A p.L157= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- ESPL1 | c.3657G>A p.L1219= | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as rs138937167; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>A p.R698= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs1339056386, COSV51931046; called by muse, mutect2
- FRMPD3 | c.426G>A p.A142= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs750213017, COSV52193110; called by muse, mutect2, varscan2
- IGHV3-23 | c.75G>A p.E25= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs970937457; called by muse, varscan2
- MORC4 | c.453A>G p.L151= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs1440218719; called by muse, mutect2, varscan2
- MYH8 | c.5190G>A p.K1730= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as COSV101238392; called by muse, varscan2
- PARD3 | c.1987A>C p.R663= | Silent (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- PELI3 | c.531C>T p.G177= | Silent (SNP) | VAF 86/253 reads (34%) | catalogued as rs758860911; called by muse, mutect2, varscan2
- PSD | c.1317C>T p.F439= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, varscan2
- PSD | c.1206C>T p.F402= | Silent (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- RHAG | c.571C>A p.R191= | Silent (SNP) | VAF 41/396 reads (10%) | catalogued as rs758540029, COSV57705030; called by muse, mutect2, varscan2
- RPP30 | c.51T>C p.A17= | Silent (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- STAP2 | c.645C>T p.I215= | Silent (SNP) | VAF 14/253 reads (6%) | catalogued as COSV99696801; called by muse, mutect2
- TGIF2LX | c.177C>T p.A59= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- ZBTB7C | c.906G>A p.P302= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs142951397; called by muse, mutect2, varscan2
- ZNF615 | c.1986G>A p.L662= | Silent (SNP) | VAF 84/223 reads (38%) | catalogued as rs772290608, COSV65034251; called by muse, mutect2, varscan2
- ZNF70 | c.1296G>A p.S432= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as rs752309236; called by muse, mutect2, varscan2
- ABCF3 | c.-63G>A | 5'UTR (SNP) | VAF 38/104 reads (37%) | catalogued as COSV99490240; called by mutect2, varscan2
- ABHD17A | c.*268C>T | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- ADAMTS7 | c.1467+62C>A | Intron (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- AFF2 | c.*1866C>T | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- AP3B2 | c.1488+144G>A | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, varscan2
- ARHGEF9 | c.-470G>A | 5'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- AVIL | c.-70G>T | 5'UTR (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3937C>T | Intron (SNP) | VAF 49/94 reads (52%) | catalogued as rs1468388952; called by muse, mutect2, varscan2
- CHRM3 | c.*611T>G | 3'UTR (SNP) | VAF 13/61 reads (21%) | catalogued as rs1414400227; called by muse, mutect2, varscan2
- CSPG5 | c.*225G>A | 3'UTR (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2, varscan2
- DDX20 | c.1021+15T>C | Intron (SNP) | VAF 103/209 reads (49%) | called by muse, mutect2, varscan2
- DENND1B | c.921+18del | Intron (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- EED | c.1199+140C>A | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- EIF1B | c.*379A>C | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- EPG5 | c.*3645C>T | 3'UTR (SNP) | VAF 8/62 reads (13%) | catalogued as rs1350783266; called by muse, mutect2
- EPS15L1 | c.*88C>T | 3'UTR (SNP) | VAF 7/77 reads (9%) | catalogued as rs996374683; called by muse, mutect2
- FAM126A | c.153+44T>C | Intron (SNP) | VAF 59/184 reads (32%) | called by muse, mutect2, varscan2
- FAM131B | c.*1444G>T | 3'UTR (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- FDFT1 | c.*216T>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- FFAR4 | c.*580G>T | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- FRG2C | c.*853C>A | 3'UTR (SNP) | VAF 24/349 reads (7%) | catalogued as rs1203419413; called by muse, mutect2
- GCNT2 | c.925+86del | Intron (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- GRAMD1C | c.*1553_*1555del | 3'UTR (DEL) | VAF 9/68 reads (13%) | catalogued as rs1221396563; called by mutect2, pindel, varscan2
- GSS | c.1301+76A>G | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*1340A>C | 3'UTR (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- HELLPAR | n.203238A>G | RNA (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- HNF1B | c.*343C>A | 3'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- HOXB8 | c.*329A>C | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- HYLS1 | c.*279del | 3'UTR (DEL) | VAF 12/108 reads (11%) | called by mutect2, varscan2
- INHBB | c.*728T>C | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- ISCA2 | c.*380T>C | 3'UTR (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- KCNH8 | c.571-1073G>A | Intron (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- KEL | c.1204-57G>T | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- KLF4 | c.1100-38A>G | Intron (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- LHFPL1 | c.*735G>A | 3'UTR (SNP) | VAF 54/105 reads (51%) | called by muse, mutect2, varscan2
- LRRC10B | c.*837G>A | 3'UTR (SNP) | VAF 14/213 reads (7%) | catalogued as rs944036798, COSV55660442; called by muse, mutect2
- LRRN3 | c.-242G>A | 5'UTR (SNP) | VAF 70/201 reads (35%) | called by muse, mutect2, varscan2
- MARCHF4 | c.*1320C>T | 3'UTR (SNP) | VAF 63/148 reads (43%) | catalogued as rs1367015220; called by muse, mutect2, varscan2
- MDFIC | c.*934A>G | 3'UTR (SNP) | VAF 22/203 reads (11%) | called by muse, mutect2, varscan2
- MEAF6 | c.*1598T>A | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- MPEG1 | c.*57G>A | 3'UTR (SNP) | VAF 60/93 reads (65%) | called by muse, mutect2, varscan2
- MTTP | c.393+63G>T | Intron (SNP) | VAF 8/102 reads (8%) | catalogued as rs1320804131; called by muse, mutect2
- NFATC2 | c.-32C>T | 5'UTR (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- NR3C1 | c.*2449C>G | 3'UTR (SNP) | VAF 36/376 reads (10%) | called by muse, mutect2
- PCDH11X | c.*3129T>C | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- PGAP2 | c.525+238G>A | Intron (SNP) | VAF 6/81 reads (7%) | catalogued as rs1310376697; called by muse, mutect2
- PIGV | c.*16G>A | 3'UTR (SNP) | VAF 58/360 reads (16%) | called by muse, varscan2
- POU3F3 | c.*1020A>C | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- PRLR | c.*3428C>A | 3'UTR (SNP) | VAF 9/148 reads (6%) | catalogued as rs1039999121; called by muse, mutect2
- RAN | c.*318G>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- RCC1 | c.-261-149_-261-143del | Intron (DEL) | VAF 26/44 reads (59%) | called by mutect2, pindel
- RECQL5 | c.*308T>C | 3'UTR (SNP) | VAF 64/225 reads (28%) | catalogued as rs757686474; called by muse, mutect2, varscan2
- RHBDF1 | c.248+52G>A | Intron (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.*2030G>C | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- RPRM | c.*20G>A | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- RRP15 | c.*6332A>C | 3'UTR (SNP) | VAF 52/104 reads (50%) | catalogued as rs1330103100; called by muse, mutect2, varscan2
- SERTAD4 | c.*715A>C | 3'UTR (SNP) | VAF 23/45 reads (51%) | catalogued as rs1465569305; called by muse, mutect2, varscan2
- SLC4A2 | c.3645+47G>A | Intron (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- SMCO1 | c.*616A>T | 3'UTR (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- SMYD3 | c.532-95G>T | Intron (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- SNX16 | c.*375G>T | 3'UTR (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2, varscan2
- SORL1 | c.*2255_*2256insTAAAA | 3'UTR (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- SP100 | c.108-2454G>T | Intron (SNP) | VAF 43/240 reads (18%) | called by mutect2, varscan2
- SRSF10 | chr1:23980436 T>C | 5'Flank (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- STEAP4 | c.984+597C>A | Intron (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- TAGLN2 | chr1:159918293 C>T | 3'Flank (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- TCF7 | c.*354C>G | 3'UTR (SNP) | VAF 47/159 reads (30%) | called by muse, mutect2, varscan2
- TENM1 | c.*559T>A | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105265822 G>A | 3'Flank (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- TMEM127 | c.*1144A>G | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- TNFAIP2 | c.*688C>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- TTC9 | c.*3057C>T | 3'UTR (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- USP54 | c.-17-157C>G | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- VAV2 | c.*893G>T | 3'UTR (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- ZNF207 | c.1117-92C>T | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- ZNF583 | chr19:56425500 G>A | 3'Flank (SNP) | VAF 9/62 reads (15%) | catalogued as rs1160112857; called by muse, mutect2, varscan2
- ZNF697 | c.*1486G>C | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*714A>T | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.642+52A>C | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
